CCDI case PBCMZU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/578a46b5-d9c5-4b45-af52-c7feff20b953

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,404 days).

Biospecimens (3 samples)
- Sample 0DVPN8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPPB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
